Gene-level copy-number profile of tumor specimen TCGA-R6-A6XQ-01B from TCGA case TCGA-R6-A6XQ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G3; Age at diagnosis: 58.6 years (21,410 days).
Specimen TCGA-R6-A6XQ-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.41cabb2a-ef3b-42e2-af1c-74eaacc1a169.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-R6-A6XQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b64aa553-50c1-4053-b4aa-c669e969adb7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 128; copy number 1: 6; copy number 2: 3,253; copy number 3: 12,695; copy number 4: 20,536; copy number 5: 17,567; copy number 6: 3,428; copy number 7: 812; copy number 8: 1,177; copy number 9: 40; copy number 10: 28; copy number 11: 1; copy number 16: 51; copy number 19: 52; copy number 20: 9; copy number 21: 8; copy number 22: 15; copy number 26: 5; copy number 30: 2; copy number 31: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-R6-A6XQ-01B-11D-A33D-01): tumor purity 0.79, ploidy 4.08, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 128 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr4:90,838,903–90,839,037, 1 gene: TMSB4XP8.
- chr16:78,525,189–78,553,296, 3 genes: AC046158.4, AC046158.2, AC046158.3.
- chr19:10,960,932–11,079,426, 4 genes (within-gene range 0–3): SMARCA4, AC011442.1, RN7SL192P, AC006127.1.
- chr21:10,328,411–17,894,485, 118 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 212 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:4,871,717–5,154,757, 23 genes, copy number 9 (within-gene range 5–9): OR51H2P, OR51T1, OR51A6P, OR51A7, OR51G2, OR51G1, OR51A3P, OR51A4, OR51A2, OR51A5P, OR51L1, OR51P1P, OR52J2P, OR52J3, OR52E2, OR52E1, OR52S1P, OR52E3P, OR52J1P, AC113331.1, OR52A4P, OR52A5, OR52A1.
- chr11:22,813,799–23,521,202, 10 genes, copy number 9: SVIP, AC006299.1, CCDC179, LINC02718, AC100767.2, WIZP1, MIR8054, AC100767.1, THAP12P4, AC068472.1.
- chr11:41,122,907–41,426,504, 2 genes, copy number 30: RNU6-365P, AC090138.1.
- chr11:49,098,163–49,379,669, 6 genes, copy number 20: AC118273.1, AC118273.2, TRIM77BP, UBTFL9, FOLH1, AC118942.1.
- chr11:49,406,190–49,434,438, 2 genes, copy number 16–20: CBX3P8, AC135977.1.
- chr11:69,414,307–71,252,577, 42 genes, copy number 19 (within-gene range 4–19): AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664.
- chr11:74,652,636–76,656,712, 70 genes, copy number 10–16 (broad region; genes not listed).
- chr11:79,966,805–80,327,911, 3 genes, copy number 11–20: AP001541.1, AP001284.1, AP006295.1.
- chr11:80,751,200–80,762,826, 1 gene, copy number 19 (within-gene range 6–19): LINC02720.
- chr11:98,130,239–98,131,198, 1 gene, copy number 10: AP001317.1.
- chr11:100,687,288–101,872,562, 8 genes, copy number 21 (within-gene range 5–21): ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1.
- chr11:102,746,968–102,836,766, 1 gene, copy number 19 (within-gene range 2–19): WTAPP1.
- chr11:102,766,801–102,903,953, 8 genes, copy number 19: AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P.
- chr11:103,252,217–103,293,705, 1 gene, copy number 31: AP002961.1.
- chr11:104,994,235–105,123,339, 7 genes, copy number 16 (within-gene range 6–16): CASP5, CASP1, CARD16, AP001153.2, CASP1P2, CARD17, CASP1P1.
- chr11:105,194,440–105,247,060, 2 genes, copy number 26: OR2AL1P, AP003181.1.
- chr11:109,637,468–109,823,893, 2 genes, copy number 9: AP003102.1, LINC02715.
- chr11:109,907,004–110,050,160, 5 genes, copy number 9: TFAMP2, AP001981.2, RPSAP50, AP001981.1, AP001889.1.
- chr11:116,609,995–117,098,437, 15 genes, copy number 22 (within-gene range 7–22): AP000770.1, LINC02702, BUD13, AP006216.1, ZPR1, APOA5, AP006216.2, AP006216.3, APOA4, APOC3, APOA1, APOA1-AS, SIK3, RNY4P6, AP000936.3.
- chr11:127,940,913–128,241,441, 3 genes, copy number 26: DNAJB6P1, LINC02725, LINC02098.

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
